TARGET case TARGET-40-PATMXR — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9307a8d-9159-5a7e-85cd-8c66221cb0b0

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Age at index: 20 years; Vital status: Dead; Days to death: 386 days (1.1 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Classification of tumor: primary; Age at diagnosis: 20.9 years (7,631 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 386 days (1.1 years); Sites of involvement: Lung, NOS / Bone, NOS.
   Treatment given: Protocol identifier: AOST06P1.

Follow-up (2 entries)
- Days to follow up: 68 days; Progression or recurrence: Yes; Days to progression: 68 days; Days to first event: 68 days; First event: Relapse.
- Days to follow up: 386 days (1.1 years); Progression or recurrence: Yes; Progression or recurrence type: Local; Year of follow up: 2011.

Biospecimens (2 samples)
- Sample TARGET-40-PATMXR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-PATMXR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 386
- Disease at diagnosis: Metastatic
- Metastasis site: Bone and lung
- Primary tumor site: Leg/foot
- Specific tumor site: Femur
- Primary site progression: Yes

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-PATMXR-01A-01:
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 82
- % Normal: Top from Biopsy: 15
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 3
- PASS/FAIL: PASS
